Gene-level copy-number profile of tumor specimen TCGA-60-2708-01A from TCGA case TCGA-60-2708, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.9 years (23,691 days).
Specimen TCGA-60-2708-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.706cd8d1-0775-4bf6-ad8b-3c7e1a64c5ff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2708-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0e9346a-76fe-4a51-bfd2-10e32b3e81c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 2,736; copy number 2: 25,770; copy number 3: 15,192; copy number 4: 9,223; copy number 5: 3,490; copy number 6: 2,841; copy number 7: 150; copy number 8: 215; copy number 9: 114; copy number 11: 20; copy number 13: 2; copy number 14: 25; copy number 23: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2708-01A-01D-0844-01): tumor purity 0.58, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,751,512–88,618,934, 14 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34.
- chr13:100,603,625–100,675,093, 2 genes (within-gene range 0–1): TMTC4, COX5BP6.
- chr21:41,304,212–41,954,018, 20 genes (within-gene range 0–2): FAM3B, MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,862 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–152,936,981, 2,921 genes, copy number 5 (broad region; genes not listed).
- chr8:34,784,028–34,874,633, 2 genes, copy number 13: LINC01288, AC087343.1.
- chr8:38,269,704–38,382,272, 1 gene, copy number 23 (within-gene range 4–23): NSD3.
- chr8:38,335,981–38,409,527, 3 genes, copy number 23: AC087362.1, AC087623.2, LETM2.
- chr8:38,408,048–38,408,742, 1 gene, copy number 23: AC087623.3.
- chr8:43,672,823–83,408,900, 566 genes, copy number 5 (broad region; genes not listed).
- chr8:111,376,639–145,066,685, 524 genes, copy number 5–9 (broad region; genes not listed).
- chr14:18,333,726–49,852,821, 801 genes, copy number 6–14 (within-gene range 4–14) (broad region; genes not listed).
- chr20:4,475,638–32,743,567, 498 genes, copy number 6–8 (broad region; genes not listed).
- chr21:10,328,411–23,131,206, 169 genes, copy number 6–7 (broad region; genes not listed).
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,736. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
